Gene-level copy-number profile of tumor specimen TCGA-EE-A2A6-06A from TCGA case TCGA-EE-A2A6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.8 years (17,468 days).
Specimen TCGA-EE-A2A6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.0960bd30-0f0d-4405-a32d-19b6070edd8a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2A6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1fe78ff3-e637-428c-9aa5-893223c17c87

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,242; copy number 2: 36,165; copy number 3: 8,324; copy number 4: 4,983; copy number 6: 100.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 100 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:221,418,027–228,841,689, 94 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:134,527,567–134,970,729, 6 genes, copy number 6 (within-gene range 4–6): AKR1B10, AKR1B15, BPGM, AC009276.1, TUBB3P2, CALD1.

Autosomal genes at a single copy (total copy number 1): 7,821. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
